Surgical pathology report (de-identified scan), TCGA case TCGA-CV-7429, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CV-7429-01A (Primary Tumor).

[page 1 of 3]
SUPPLEMENTAL REPORT

COMMENT: Decalcified sections of the anterior mandibular resection margin are free of carcinoma. Decalcified sections of the condyle of the right mandible (part B) are free of carcinoma.

This supplemental report is issued to give the results of the decalcified sections; the original diagnoses remain unchanged.

DIAGNOSIS

- (A) CORONOID PROCESS OF THE RIGHT MANDIBLE:
POORLY DIFFERENTIATED SQUAMOUS CARCINOMA INVOLVING BONE.
- (B) CONDYLE OF THE RIGHT MANDIBLE:
POORLY DIFFERENTIATED SQUAMOUS CARCINOMA INVOLVING SOFT TISSUE.
Decalcification pending.
- (C) RIGHT COMPOSITE RESECTION AND NECK DISSECTION:
INVASIVE SQUAMOUS CARCINOMA, POORLY DIFFERENTIATED, INVOLVING
RIGHT BUCCAL MUCOSA, MANDIBLE, AND FLOOR OF MOUTH (SEE COMMENT).
Skin and final soft tissue margins of resection, no tumor present
(see comment).
Anterior mandible margin of resection pending decalcification.
PERINEURAL INVASION PRESENT.
METASTATIC SQUAMOUS CARCINOMA INVOLVING 14 OF 24 LYMPH NODES
(3 OF 3 LEVEL I, 1 OF 1 LEVEL II, 5 OF 6 LEVEL III, 5 OF 14
LEVEL IV) (SEE COMMENT).
- (D) TONGUE MARGIN:
Squamous mucosa and skeletal muscle, no tumor present.
- (E) RIGHT PALATE MARGIN:
Squamous mucosa and minor salivary glands, no tumor present.
- (F) LATERAL PTERYGOID:
POORLY DIFFERENTIATED SQUAMOUS CARCINOMA.
- (G) BUCCAL MARGIN:
Squamous mucosa, no tumor present.
- (H) NEW PTERYGOID MARGIN:
POORLY DIFFERENTIATED SQUAMOUS CARCINOMA.
- (I) RIGHT MAXILLARY TUBEROSITY:
Squamous mucosa, no tumor present.
- (J) TEETH:
Gross evaluation only.

[page 2 of 3]
[REDACTED]

(K) FINAL MARGIN PTERYGOID MUSCLE:
skeletal muscle, no tumor present (see comment).

[REDACTED]

COMMENT

The tumor measures 8.5 x 8.5 x 8.0 cm and diffusely involves the right buccal space, mandible, and floor of mouth soft tissue. Although two pterygoid margins were initially positive, the final pterygoid margin of excision (part K) is free of tumor. The anterior mandibular margin of excision and condyle of the mandible are pending decalcification and an addendum report will follow.

The largest lymph node metastasis completely replaces a 5.0 cm lymph node; extranodal extension of approximately 0.1 cm is present.

[REDACTED]

GROSS DESCRIPTION

(A) CORONOID PROCESS OF MANDIBLE, RIGHT - One irregular bone fragment (1.5 x 1.4 x 0.3 cm). Entirely submitted to the bone lab for decalcification. [REDACTED]

(B) CONDYLE OF MANDIBLE, RIGHT - One irregular bone fragment with focal soft tissue (4.0 x 2.4 x 2.0 cm). The bone is submitted to the bone lab for decalcification and further processing. The soft tissue is submitted in B1. [REDACTED]

(C) RIGHT COMPOSITE RESECTION AND NECK DISSECTION - A right composite mandibular resection including right mandible, molar teeth, attached soft tissue, and skeletal muscle and skin measuring 22.0 x 16.0 x 10.0 cm in entirety. Attached tan-brown, unremarkable skin measures 14.0 x 10.0 cm. Attached neck dissection measures 8.0 x 6.0 x 4.0 cm and includes levels I-IV.

Sectioning reveals a 8.5 x 8.5 x 8.0 cm irregular firm tan-white tumor involving subcutaneous tissue, skeletal muscle, and soft tissue and extending to mandibular bone (ramus). Skin, soft tissue and bony margins of resection are grossly uninvolved by tumor.

One level I lymph node measuring 5.0 x 3.0 x 3.0 cm is grossly involved with metastatic disease. Salivary gland measuring 5.0 x 4.0 x 3.5 cm is unremarkable. Tissue is submitted for research.

INK CODE: Yellow-posterior, black-anterior.

SECTION CODE: C1-C4, level I lymph nodes (C1, C2, representative sections of largest lymph node; C3, C4, one bisected lymph node each); C5, salivary gland; C6, multiple level II lymph nodes; C7-C10, level III lymph nodes (C7-C9, one bisected lymph node each; C10, multiple lymph nodes); C11-C18, level IV lymph nodes (C11, C12, one lymph node in two cassettes; C13, C14, one lymph node in two cassettes; C15, C16, one lymph node each; C17, C18, multiple

[page 3 of 3]
[REDACTED]

lymph nodes each); C19, anterior skin margin, en face; C20, posterior skin margin, en face; C21-C27, tumor; C28, C29, tumor with mandible.

Specimen is submitted to Bone Laboratory for further processing.

(D) TONGUE MARGIN STITCH ANTERIOR - A portion of mucosa covered soft tissue (4.2 x 0.8 x 0.5 cm). No discrete lesions are identified. Entirely submitted.

INK CODE: Blue-anterior; yellow-posterior.

SECTION CODE: D1, anterior half, frozen section; D2, posterior half, frozen section.

*FS/DX: SQUAMOUS MUCOSA AND SKELETAL MUSCLE, NO TUMOR PRESENT.

(E) RIGHT PALATE MARGIN STITCH ANTERIOR - A portion of mucosa covered soft tissue (4.4 x 1.2 x 0.6 cm). No discrete lesions are identified. Entirely submitted.

INK CODE: Blue-anterior; yellow-posterior.

SECTION CODE: E1, anterior half, frozen section; E2, posterior half, frozen section.

*FS/DX: NO TUMOR PRESENT.

(F) LATERAL PTERYGOID MARGIN - A single portion of red soft tissue (1.8 x 0.8 x 0.7 cm). No discrete lesions are identified. Entirely submitted for frozen section in F.

*FS/DX: POORLY DIFFERENTIATED CARCINOMA.

(G) BUCCAL MARGIN - A non-oriented portion of mucosa covered soft tissue (3.4 x 0.9 x 0.4 cm). No discrete lesions are identified. Entirely submitted for frozen section in G.

*FS/DX: NO TUMOR PRESENT.

(H) NEW PTERYGOID MARGIN - A portion of irregular red-tan soft tissue (3.7 x 1.8 x 0.9 cm) in which no discrete lesions are identified. Entirely submitted for frozen section in H1 and H2, en face.

*FS/DX: POORLY DIFFERENTIATED CARCINOMA.

(I) RIGHT MAXILLARY TUBEROSITY - Rectangular portion of tan-pink mucosa (0.7 x 0.6 cm, depth 0.4 cm). Entirely submitted for frozen section in I.

*FS/DX: SQUAMOUS MUCOSA, NO TUMOR PRESENT.

(J) TEETH - Fifteen teeth and fragments of teeth in aggregate 7.0 x 5.0 x 2.0 cm. Submitted for gross examination only.

(K) FINAL MARGIN PTYERGOID MUSCLE - Cauterized fragment of muscle 1.7 x 1.5 x 0.3 cm. Entirely submitted, K.

SNOMED CODES

M-80703 T-D166X

Source: NCI Genomic Data Commons file d910e988-959e-47e1-847c-5fec75e7c5a9 (TCGA-CV-7429.EF7C8E25-1225-49A5-BBD6-0E2DC4A72568.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).